TCGA case TCGA-12-3644 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f6c6e2c9-a3d6-4b81-a421-04ffef6b8744

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 47 years; Vital status: Dead; Days to death: 1,818 days (5.0 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 47.8 years (17,468 days); Year of diagnosis: 2004; Method of diagnosis: Excisional Biopsy; Prior treatment: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine Implant; Treatment intent type: Adjuvant; Days to treatment start: 37 days; Days to treatment end: 37 days; Number of cycles: 1; Treatment dose: 62 Wafer; Prescribed dose: 8; Prescribed dose units: Wafer; Route of administration: Intratumoral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 72 days; Days to treatment end: 119 days; Treatment dose: 5,940 cGy; Number of fractions: 32; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 72 days; Days to treatment end: 119 days; Number of cycles: 2; Treatment dose: 3,200 mg; Prescribed dose: 200; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 134 days; Days to treatment end: 179 days; Number of cycles: 1; Treatment dose: 190 mg; Prescribed dose: 110; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 179 days; Days to treatment end: 486 days (1.3 years); Number of cycles: 10; Treatment dose: 17,000 mg; Prescribed dose: 200; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Recurrent Disease; Days to treatment start: 861 days (2.4 years); Days to treatment end: 891 days (2.4 years); Number of cycles: 1; Treatment dose: 1,700 mg; Prescribed dose: 200; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Erlotinib Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 891 days (2.4 years); Days to treatment end: 1,030 days (2.8 years); Treatment dose: 21,000 mg; Prescribed dose: 150; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Recurrent Disease; Days to treatment start: 891 days (2.4 years); Days to treatment end: 891 days (2.4 years); Treatment dose: 1,800 cGy; Number of fractions: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sirolimus; Initial disease status: Recurrent Disease; Days to treatment start: 891 days (2.4 years); Days to treatment end: 1,030 days (2.8 years); Treatment dose: 700 mg; Prescribed dose: 5; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Recurrent Disease; Days to treatment start: 1,030 days (2.8 years); Days to treatment end: 1,142 days (3.1 years); Number of cycles: 7; Treatment dose: 10,080 mg; Prescribed dose: 50; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Recurrent Disease; Days to treatment start: 1,142 days (3.1 years); Days to treatment end: 1,180 days (3.2 years); Number of cycles: 1; Treatment dose: 3,500 mg; Prescribed dose: 75; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: O6-Benzylguanine; Initial disease status: Recurrent Disease; Days to treatment start: 1,150 days (3.1 years); Days to treatment end: 1,154 days (3.2 years); Treatment dose: 250 mg; Prescribed dose: 30; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: O6-Benzylguanine; Initial disease status: Recurrent Disease; Days to treatment start: 1,150 days (3.1 years); Days to treatment end: 1,154 days (3.2 years); Treatment dose: 600 mg; Prescribed dose: 120; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Recurrent Disease; Days to treatment start: 1,194 days (3.3 years); Days to treatment end: 1,583 days (4.3 years); Treatment dose: 18,900 mg; Prescribed dose: 10; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 1,194 days (3.3 years); Days to treatment end: 1,583 days (4.3 years); Number of cycles: 9; Treatment dose: 5,400 mg; Prescribed dose: 125; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Recurrent Disease; Days to treatment start: 1,583 days (4.3 years); Days to treatment end: 1,611 days (4.4 years); Treatment dose: 1,400 mg; Prescribed dose: 10; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Erlotinib Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 1,583 days (4.3 years); Days to treatment end: 1,611 days (4.4 years); Treatment dose: 4,200 mg; Prescribed dose: 150; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Hydroxyurea; Initial disease status: Recurrent Disease; Days to treatment start: 1,583 days (4.3 years); Days to treatment end: 1,611 days (4.4 years); Number of cycles: 1; Treatment dose: 14,000 mg; Prescribed dose: 500; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sirolimus; Initial disease status: Recurrent Disease; Days to treatment start: 1,583 days (4.3 years); Days to treatment end: 1,611 days (4.4 years); Treatment dose: 140 mg; Prescribed dose: 5; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Recurrent Disease; Days to treatment start: 1,611 days (4.4 years); Days to treatment end: 1,639 days (4.5 years); Treatment dose: 1,400 mg; Prescribed dose: 10; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Erlotinib Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 1,611 days (4.4 years); Days to treatment end: 1,639 days (4.5 years); Treatment dose: 4,200 mg; Prescribed dose: 150; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Hydroxyurea; Initial disease status: Recurrent Disease; Days to treatment start: 1,611 days (4.4 years); Days to treatment end: 1,639 days (4.5 years); Number of cycles: 1; Treatment dose: 14,000 mg; Prescribed dose: 500; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Isotretinoin; Initial disease status: Recurrent Disease; Days to treatment start: 1,611 days (4.4 years); Days to treatment end: 1,639 days (4.5 years); Treatment dose: 1,680 mg; Prescribed dose: 80; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sirolimus; Initial disease status: Recurrent Disease; Days to treatment start: 1,611 days (4.4 years); Days to treatment end: 1,639 days (4.5 years); Treatment dose: 140 mg; Prescribed dose: 5; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Recurrent Disease; Days to treatment start: 1,639 days (4.5 years); Days to treatment end: 1,722 days (4.7 years); Treatment dose: 4,200 mg; Prescribed dose: 10; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Chloroquine; Initial disease status: Recurrent Disease; Days to treatment start: 1,639 days (4.5 years); Days to treatment end: 1,722 days (4.7 years); Treatment dose: 21,000 mg; Prescribed dose: 500; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 1,639 days (4.5 years); Days to treatment end: 1,722 days (4.7 years); Number of cycles: 3; Treatment dose: 1,200 mg; Prescribed dose: 125; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Isotretinoin; Initial disease status: Recurrent Disease; Days to treatment start: 1,639 days (4.5 years); Days to treatment end: 1,722 days (4.7 years); Treatment dose: 1,680 mg; Prescribed dose: 80; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Recurrent Disease; Days to treatment start: 1,639 days (4.5 years); Days to treatment end: 1,722 days (4.7 years); Number of cycles: 3; Treatment dose: 1,825 mg; Prescribed dose: 150; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Recurrent Disease; Days to treatment start: 1,765 days (4.8 years); Days to treatment end: 1,806 days (4.9 years); Treatment dose: 2,100 mg; Prescribed dose: 10; Prescribed dose units: mg; Route of administration: Intravenous.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 51.0 years (18,610 days); Days to diagnosis: 1,142 days (3.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 857 days (2.3 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (5 entries)
- Day 1,142 (post initial treatment): Progression or recurrence: Yes; Days to progression: 1,142 days (3.1 years).
- Days to follow up: 1,807 days (4.9 years); Disease response: With Tumor.
- Days to follow up: 1,818 days (5.0 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.
- Karnofsky performance status: 60; Timepoint: Post Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-12-3644-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.2.
  Slide TCGA-12-3644-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 30; Percent stromal cells: 0.
  Slide TCGA-12-3644-01A-01-BS1: Section location: Bottom; Percent tumor cells: 40; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 40; Percent stromal cells: 0.
- Sample TCGA-12-3644-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-12-3644-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Temodar.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Pharmaceutical therapy drug name: Avastin; Therapy regimen: Recurrence.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 4: Pharmaceutical therapy drug name: Temodar; Therapy regimen: Recurrence.
- Drug treatment 5: Pharmaceutical therapy drug name: Accutane; Therapy regimen: Recurrence.
- Drug treatment 6: Pharmaceutical therapy drug name: Hydroxyuerea; Therapy regimen: Recurrence.
- Drug treatment 7: Pharmaceutical therapy drug name: Rapamycin; Therapy regimen: Recurrence.
- Drug treatment 8: Pharmaceutical therapy drug name: 06BG; Therapy regimen: Recurrence.
- Drug treatment 9: Pharmaceutical therapy drug name: Ccnu.
- Drug treatment 10: Pharmaceutical therapy drug name: CPT 11; Therapy regimen: Recurrence.
- Drug treatment 12: Pharmaceutical therapy drug name: Acctuane; Therapy regimen: Recurrence.
- Drug treatment 14: Pharmaceutical therapy drug name: Tarceva; Therapy regimen: Recurrence.
- Drug treatment 23: Pharmaceutical therapy drug name: Gliadel Wafer.
- Drug treatment 23, Route of administrations: Route of administration: Intum.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,818 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,818 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,142 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-12-3644-01A-01D-0911-01): tumor purity 0.83, ploidy 1.98, whole-genome doublings 0.
